Gene-level copy-number profile of tumor specimen TCGA-DX-A23U-01A from TCGA case TCGA-DX-A23U, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 81.9 years (29,905 days).
Specimen TCGA-DX-A23U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.ebd9bc36-03a7-419f-ace8-2402959a914d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A23U-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/10b3c7e3-1ec5-49bf-a796-7c681933d4ca

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,421; copy number 2: 56,435; copy number 3: 239; copy number 4: 185; copy number 5: 166; copy number 6: 76; copy number 7: 52; copy number 8: 37; copy number 9: 13; copy number 10: 22; copy number 12: 24; copy number 13: 41; copy number 14: 2; copy number 15: 8; copy number 17: 8; copy number 18: 63; copy number 21: 3; copy number 23: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A23U-01A-11D-A26F-01): tumor purity 0.24, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 533 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:51,980,473–53,328,469, 61 genes, copy number 9–18 (within-gene range 2–18) (broad region; genes not listed).
- chr1:53,413,149–53,440,020, 1 gene, copy number 8: SLC25A3P1.
- chr1:54,026,681–54,225,464, 11 genes, copy number 5 (within-gene range 2–5): TMEM59, AL353898.3, TCEANC2, MIR4781, AL353898.1, AL353898.2, AL357673.1, CDCP2, AL357673.2, CYB5RL, MRPL37.
- chr1:54,236,440–54,287,371, 2 genes, copy number 5: SSBP3-AS1, AL161644.1.
- chr1:55,329,288–56,070,513, 1 gene, copy number 17 (within-gene range 2–17): AL603840.1.
- chr1:55,484,871–55,484,972, 1 gene, copy number 17: Y_RNA.
- chr1:56,994,778–59,296,491, 28 genes, copy number 13–23 (within-gene range 2–23): DAB1, AL390243.1, RPS20P5, DAB1-AS1, HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1, AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1.
- chr1:69,551,848–69,563,715, 1 gene, copy number 21: AL359894.1.
- chr1:69,606,855–69,608,301, 1 gene, copy number 21: SGO1P1.
- chr1:88,684,222–88,836,255, 2 genes, copy number 12 (within-gene range 2–12): PKN2, RNU6-125P.
- chr1:150,255,095–151,729,805, 81 genes, copy number 6–13 (broad region; genes not listed).
- chr1:157,121,191–157,598,085, 11 genes, copy number 12: ETV3, CYCSP52, AL357143.1, AL357143.2, AL138900.1, LINC02772, AL138900.2, AL732406.1, AL353899.1, FCRL5, FCRL4.
- chr1:159,951,492–160,828,261, 37 genes, copy number 6–18: SLAMF9, LINC01133, AL513485.1, KCNJ10, AL513302.1, PIGM, AL121987.1, KCNJ9, IGSF8, ATP1A2, ATP1A4, CASQ1, AL121987.2, PEA15, DCAF8, AL139011.2, AL139011.1, RPSAP18, PEX19, COPA, SUMO1P3, Y_RNA, NCSTN, NHLH1, RNU4-42P, VANGL2, SLAMF6, AL138930.1, CD84, SLAMF1, SETP9, AL121985.1, CD48, SLAMF7, AL121985.3, AL121985.2, LY9.
- chr1:167,591,392–167,708,696, 3 genes, copy number 15 (within-gene range 2–15): AL031733.1, AL031733.2, RCSD1.
- chr1:171,600,621–171,684,438, 4 genes, copy number 10: MYOCOS, MYOC, PFN1P1, RPL4P3.
- chr1:171,841,498–172,418,466, 1 gene, copy number 6 (within-gene range 2–13): DNM3.
- chr1:172,138,397–172,444,086, 7 genes, copy number 6–13 (within-gene range 2–13): DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC.
- chr1:173,417,793–173,612,772, 4 genes, copy number 12 (within-gene range 2–12): PRDX6-AS1, PRDX6, SLC9C2, AL139142.1.
- chr1:188,013,642–188,156,180, 3 genes, copy number 7–9 (within-gene range 2–9): AL136372.2, AL136372.1, RN7SKP156.
- chr1:188,508,538–189,037,564, 6 genes, copy number 12 (within-gene range 2–12): AL929288.1, AL929288.2, RPS3AP9, AL691515.1, AL691515.2, LINC01035.
- chr1:190,878,145–191,228,467, 5 genes, copy number 15 (within-gene range 2–15): AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680.
- chr1:194,488,103–194,488,205, 1 gene, copy number 10: RNU6-983P.
- chr1:196,044,883–196,065,235, 1 gene, copy number 9: LINC01724.
- chr1:202,147,013–202,189,455, 2 genes, copy number 8–9 (within-gene range 2–9): PTPN7, PTPRVP.
- chr1:203,765,177–203,776,372, 1 gene, copy number 12: LAX1.
- chr1:204,131,062–204,558,120, 17 genes, copy number 8–13 (within-gene range 2–13): AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1.
- chr7:2,631,986–4,269,000, 15 genes, copy number 5 (within-gene range 2–5): TTYH3, AMZ1, GNA12, AC006028.1, CARD11, CARD11-AS1, RN7SKP130, AC024028.1, AC073316.1, AC073316.2, SDK1-AS1, SDK1, AC092427.1, AC011284.1, AC017000.1.
- chr7:4,775,615–9,769,513, 120 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr15:22,983,192–23,856,375, 26 genes, copy number 8 (within-gene range 2–8): TUBGCP5, ELMO2P1, GOLGA6L1, AC116165.1, GOLGA8DP, RN7SL106P, ABCB10P1, AC116165.2, MIR4509-1, AC116165.3, AC242376.1, HERC2P7, AC100756.2, AC100756.1, GOLGA8S, RN7SL536P, AC100756.3, HERC2P6, GOLGA6L2, MIR4508, MKRN3, AC126407.1, MAGEL2, NDN, AC087490.1, RNU6-741P.
- chr15:25,456,271–25,578,813, 1 gene, copy number 5 (within-gene range 3–5): LINC02250.
- chr15:26,964,917–27,541,991, 10 genes, copy number 5 (within-gene range 3–5): TVP23BP1, GABRG3, GABRG3-AS1, AC136896.1, RNA5SP391, SERPINE4P, AC144833.1, AC104002.1, AC104002.2, AC104002.3.
- chr15:29,664,477–30,045,848, 8 genes, copy number 6 (within-gene range 4–6): AC102941.2, AC022613.1, TJP1, AC022613.3, HMGN2P5, AC022613.2, NCAPGP2, AC111152.2.
- chr16:71,080,866–71,114,000, 2 genes, copy number 6: AC138625.2, AC138625.1.
- chr21:15,368,966–19,345,312, 58 genes, copy number 5–7 (within-gene range 2–7): AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P, RAD23BP3, USP25, RBPMSLP, MIR99AHG, RNU6-426P, VDAC2P1, RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1, NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3, CHODL, AF130417.1, TMPRSS15, AL109763.1, MIR548XHG, AF240627.1, MIR548X, PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
